Gene-level copy-number profile of tumor specimen TCGA-DX-A3LU-01A from TCGA case TCGA-DX-A3LU, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.0 years (21,915 days).
Specimen TCGA-DX-A3LU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.730898d3-cfde-45d2-86db-3133915f4087.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A3LU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1bc3e65f-2d4a-4765-8aa0-11af475077a3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,387; copy number 2: 55,258; copy number 3: 1,111; copy number 4: 678; copy number 5: 88; copy number 6: 35; copy number 7: 22; copy number 8: 27; copy number 9: 18; copy number 10: 16; copy number 11: 5; copy number 12: 2; copy number 13: 34; copy number 14: 45; copy number 15: 59; copy number 17: 6; copy number 18: 21; copy number 23: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A3LU-01A-11D-A21P-01): tumor purity 0.42, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 382 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,415,384–60,640,507, 29 genes, copy number 6–15: OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748.
- chr1:62,194,849–62,319,434, 5 genes, copy number 5: L1TD1, AL162739.1, Y_RNA, KANK4, RNU6-371P.
- chr3:73,999,805–74,521,140, 4 genes, copy number 13 (within-gene range 2–13): LINC02047, AC016930.1, AKR1B1P2, CNTN3.
- chr3:77,316,752–77,317,598, 1 gene, copy number 10: VDAC1P7.
- chr3:79,957,566–79,958,142, 1 gene, copy number 11: HMGB1P38.
- chr5:23,443,586–23,689,386, 3 genes, copy number 13: PRDM9, AC109445.1, AC108103.1.
- chr6:39,792,298–41,406,561, 38 genes, copy number 5–17: DAAM2, AL592158.1, DAAM2-AS1, MOCS1, TUBBP9, FO393411.1, AL139275.2, TDRG1, LINC00951, AL139275.1, LRFN2, RNU6-250P, AL359475.1, AL033380.1, AL583854.1, UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2.
- chr6:41,736,711–42,722,597, 29 genes, copy number 15: PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10, TRERF1, AL591473.1, UBR2, RNU6-890P, PRPH2.
- chr6:43,011,143–43,425,283, 25 genes, copy number 8 (within-gene range 3–8): MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1, PTK7, SRF, CUL9, AL133375.1, DNPH1, TTBK1, SLC22A7, CRIP3, ZNF318, RPL12P47, AL583834.1, RPS2P28, AL590383.1, AL359813.1, AL359813.2.
- chr6:44,089,242–44,307,506, 13 genes, copy number 5–14: AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B.
- chr6:44,278,734–44,313,347, 2 genes, copy number 5: TCTE1, AARS2.
- chr6:46,903,471–46,909,078, 1 gene, copy number 8: ADGRF5-AS1.
- chr6:47,374,561–47,627,263, 5 genes, copy number 9–12 (within-gene range 2–12): AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1.
- chr6:50,514,035–50,773,033, 3 genes, copy number 13 (within-gene range 2–13): AL360175.1, AL135908.1, TFAP2D.
- chr6:52,497,408–52,870,329, 14 genes, copy number 9: TRAM2, TRAM2-AS1, AL109918.2, AL109918.1, TMEM14A, GSTA8P, SREK1IP1P2, GSTA7P, GSTA2, GSTA12P, GSTA1, GSTA6P, GSTA5, GSTA11P.
- chr6:98,179,499–99,589,899, 18 genes, copy number 5: EIF4EBP2P3, AL590727.1, AL589826.1, AL589826.2, POU3F2, FBXL4, AL078603.1, MIR548AI, BDH2P1, FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1.
- chr6:100,177,209–100,178,192, 1 gene, copy number 12: AL080285.1.
- chr6:106,629,578–106,788,148, 6 genes, copy number 6: QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587.
- chr6:111,259,327–111,445,354, 1 gene, copy number 5 (within-gene range 2–5): MFSD4B.
- chr6:111,299,028–111,606,906, 10 genes, copy number 5 (within-gene range 2–5): REV3L, AL080317.2, FCF1P5, REV3L-IT1, BRD7P4, TRAF3IP2-AS1, AL136310.1, AL008730.1, TRAF3IP2, Z97989.1.
- chr6:148,272,304–148,552,048, 1 gene, copy number 6 (within-gene range 3–6): SASH1.
- chr6:148,478,693–149,076,990, 5 genes, copy number 6 (within-gene range 4–6): CYP51A1P3, SNRPEP6, RPSAP40, UST, UST-AS1.
- chr8:150,584–545,781, 17 genes, copy number 5: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP.
- chr9:114,572,901–115,402,644, 15 genes, copy number 5: AL160275.2, ATP6V1G1, TMEM268, Y_RNA, TEX53, TEX48, AL160275.1, AL390240.1, TNFSF15, AL133412.1, DELEC1, TNFSF8, TNC, AL162425.1, AL355601.1.
- chr12:54,543,111–54,687,434, 7 genes, copy number 15: AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1.
- chr12:55,362,975–55,585,471, 14 genes, copy number 6: OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1, OR6C76, AC122685.1, OR6C2, OR6C70, OR6C68, OR6C64P, OR6C4, OR2AP1.
- chr12:57,615,280–58,105,935, 34 genes, copy number 14 (within-gene range 3–14): AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr12:61,600,067–62,600,476, 15 genes, copy number 7 (within-gene range 2–7): DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P.
- chr12:67,648,338–67,729,475, 3 genes, copy number 15: DYRK2, AC078777.1, LINC02421.
- chr12:68,746,125–69,601,570, 25 genes, copy number 10–18 (within-gene range 2–18): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2.
- chr12:69,643,360–69,699,476, 2 genes, copy number 6 (within-gene range 3–6): BEST3, AC025263.3.
- chr12:69,901,918–70,243,379, 4 genes, copy number 11 (within-gene range 3–11): PRANCR, AC078922.1, LINC02821, AC092881.2.
- chr12:75,563,202–75,984,015, 1 gene, copy number 6 (within-gene range 2–23): AC078923.1.
- chr12:75,649,195–76,880,352, 30 genes, copy number 5–23: AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
